Somatic mutation profile of tumor specimen ALCH-B2AP-TTP1-A (aliquot ALCH-B2AP-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2AP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.2 years (21,261 days).
Specimen ALCH-B2AP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5afd415-9c9a-4a0a-aa63-708177532afc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AP-NB1-A (Blood Derived Normal), aliquot ALCH-B2AP-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32e5004f-153c-4ad6-a5b8-9c8eada489d2

The open-access MAF lists 106 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, RNA 6, Intron 4, Frame Shift Del 4, Splice Site 2, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 108/550 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.843del p.L282Sfs*5 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs587776656, CD982962, COSV58821884, COSV58823674, COSV58823877; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 124/554 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as rs1202457869; called by muse, mutect2, varscan2
- ANKRD30BL | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387522339; called by muse, mutect2, varscan2
- ATP6V1H | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371234673; called by muse, mutect2, varscan2
- ATR | c.2638G>T p.A880S | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV63391214; called by muse, mutect2, varscan2
- COL6A3 | c.4286-2A>G p.X1429_splice | Splice Site (SNP) | VAF 45/313 reads (14%) | catalogued as rs761453030; called by muse, mutect2, varscan2
- D2HGDH | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 107/583 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs142977491; called by muse, mutect2, varscan2
- EMB | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs751001259; called by muse, mutect2, varscan2
- GTF3C1 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 107/660 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV99852170; called by muse, mutect2, varscan2
- IPO13 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs377240680; called by muse, mutect2, varscan2
- ISCA2 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.166); catalogued as rs1463264518; called by muse, mutect2, varscan2
- KAT6A | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs143346098; called by muse, mutect2, varscan2
- KRTAP19-5 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 189/1109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); catalogued as COSV61858429; called by muse, mutect2, varscan2
- MARK2 | c.1817G>A p.R606Q (on ENST00000402010 / NM_001039469.2; = p.R551Q on NM_004954.5) | Missense Mutation (SNP) | VAF 145/687 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs1370861751; called by muse, mutect2, varscan2
- NINL | c.2800G>T p.E934* | Nonsense Mutation (SNP) | VAF 54/282 reads (19%) | catalogued as COSV54002325; called by muse, mutect2, varscan2
- NMUR1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs533098326, COSV59404733; called by muse, mutect2, varscan2
- NOS1AP | c.1159G>T p.V387L | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs868398500, COSV100723552; called by muse, mutect2, varscan2
- OR6B1 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV101281666; called by muse, mutect2, varscan2
- PLXDC2 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101023016; called by muse, mutect2, varscan2
- PRSS1 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 102/616 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100298578, COSV61192207; called by muse, varscan2
- RLF | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761133694; called by muse, mutect2, varscan2
- RPS27A | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 145/915 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs762580409, COSV55052812; called by muse, mutect2, varscan2
- SH3TC2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 122/652 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as rs764169824; called by muse, mutect2, varscan2
- SMARCA4 | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 174/754 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60802268; called by mutect2, varscan2
- A1CF | c.946A>C p.T316P | Missense Mutation (SNP) | VAF 120/640 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADPGK | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, varscan2
- ANKRD40 | c.586A>T p.I196L | Missense Mutation (SNP) | VAF 161/784 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALT4 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- BLMH | c.895_896del p.L299Ifs*7 | Frame Shift Del (DEL) | VAF 68/399 reads (17%) | called by pindel, varscan2
- CA14 | c.551T>A p.V184D | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CADPS | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- CNTFR | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTIF | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 92/401 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS1 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX39B | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 119/656 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ELAC2 | c.2251_2253del p.K751del | In Frame Del (DEL) | VAF 53/302 reads (18%) | called by mutect2, pindel, varscan2
- EYA1 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 138/731 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FFAR3 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 82/855 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.199); called by muse, mutect2
- FSIP2 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ITSN2 | c.4839T>A p.N1613K | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- KBTBD12 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNQ1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 123/593 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- KEAP1 | c.1637del p.F546Sfs*2 | Frame Shift Del (DEL) | VAF 61/288 reads (21%) | called by mutect2, pindel, varscan2
- KIF21B | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- KLHDC9 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- KRTAP26-1 | c.348G>T p.R116S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARGE1 | c.787+1G>T p.X263_splice | Splice Site (SNP) | VAF 85/491 reads (17%) | called by muse, mutect2, varscan2
- LILRB1 | c.326T>A p.I109N (on ENST00000427581; = p.I73N on NM_006669.6) | Missense Mutation (SNP) | VAF 62/595 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.118); called by muse, mutect2
- MAN1A1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MS4A8 | c.741_742delinsT p.Q247Hfs*28 | Frame Shift Del (DEL) | VAF 45/388 reads (12%) | called by pindel, varscan2*
- MYOC | c.1098C>A p.H366Q | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR2G6 | c.674T>A p.V225E | Missense Mutation (SNP) | VAF 83/525 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCDHB16 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- POLR3A | c.2616G>T p.Q872H | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R13L | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PRRC2C | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PTPRC | c.1028A>T p.Q343L | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, varscan2
- SALL1 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SMURF2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- STIM1 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 147/812 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STX3 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 93/484 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TBC1D9 | c.1340G>C p.R447P | Missense Mutation (SNP) | VAF 80/487 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TFPI | c.357A>G p.Q119= | Splice Region (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- TJP1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ1 | c.619A>T p.T207S (on ENST00000580243 / NM_001308210.2; = p.T162S on NM_005786.6) | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TSHZ2 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF845 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 100/504 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGAP40 | c.267C>A p.L89= | Silent (SNP) | VAF 95/489 reads (19%) | called by muse, mutect2, varscan2
- CAP1 | c.891C>T p.P297= | Silent (SNP) | VAF 59/280 reads (21%) | called by muse, mutect2, varscan2
- CCDC6 | c.1080G>C p.P360= | Silent (SNP) | VAF 158/802 reads (20%) | called by muse, mutect2, varscan2
- CDC42BPG | c.360G>C p.R120= | Silent (SNP) | VAF 64/334 reads (19%) | called by muse, mutect2, varscan2
- CDHR3 | c.522G>A p.L174= | Silent (SNP) | VAF 77/419 reads (18%) | catalogued as rs1444655159; called by muse, mutect2, varscan2
- DEPDC5 | c.234G>T p.R78= | Silent (SNP) | VAF 52/318 reads (16%) | called by muse, mutect2, varscan2
- DTX1 | c.57G>A p.P19= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as rs774831457, COSV57495394, COSV57500788; called by muse, mutect2, varscan2
- GPLD1 | c.2118C>T p.L706= | Silent (SNP) | VAF 86/561 reads (15%) | called by muse, mutect2, varscan2
- H3-5 | c.288C>T p.S96= | Silent (SNP) | VAF 132/577 reads (23%) | catalogued as COSV61187015; called by muse, mutect2, varscan2
- NDN | c.630C>G p.V210= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- OR11L1 | c.564C>A p.S188= | Silent (SNP) | VAF 71/471 reads (15%) | called by muse, mutect2, varscan2
- OR2L8 | c.246T>A p.S82= | Silent (SNP) | VAF 151/450 reads (34%) | catalogued as COSV100594345; called by muse, mutect2, varscan2
- PGA5 | c.801C>A p.A267= | Silent (SNP) | VAF 137/731 reads (19%) | called by muse, mutect2, varscan2
- PLCB4 | c.3495C>G p.A1165= (on ENST00000278655 / NM_182797.3; = p.R1178G on NM_000933.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 90/640 reads (14%) | catalogued as COSV99595144; called by muse, mutect2, varscan2
- RPS13 | c.363G>T p.R121= | Silent (SNP) | VAF 38/183 reads (21%) | called by muse, mutect2, varscan2
- SLC22A1 | c.1542A>G p.P514= | Silent (SNP) | VAF 89/474 reads (19%) | called by muse, mutect2, varscan2
- TANGO2 | c.339C>T p.G113= | Silent (SNP) | VAF 39/307 reads (13%) | called by muse, mutect2, varscan2
- TBCE | c.1377T>C p.C459= (on ENST00000366601; = p.C522= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 230/1214 reads (19%) | catalogued as rs147519707; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPP2 | c.1278G>T p.A426= | Silent (SNP) | VAF 75/365 reads (21%) | called by muse, mutect2, varscan2
- UNC79 | c.1290G>A p.P430= (on ENST00000393151 / NM_001346218.2; = p.P253= on NM_020818.5) | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs771758901, COSV56389906; called by muse, mutect2
- XDH | c.2655C>T p.H885= | Silent (SNP) | VAF 173/808 reads (21%) | catalogued as COSV65148266; called by muse, mutect2, varscan2
- ZBED3 | c.426C>T p.R142= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3078C>A p.A1026= | Silent (SNP) | VAF 74/497 reads (15%) | called by muse, mutect2, varscan2
- ZNF528 | c.801G>A p.K267= | Silent (SNP) | VAF 36/269 reads (13%) | catalogued as rs1424862730; called by muse, mutect2, varscan2
- AC009533.1 | n.995G>A | RNA (SNP) | VAF 80/1367 reads (6%) | called by muse, mutect2
- AC024940.1 | n.1070G>T | RNA (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- AC024940.1 | n.1069A>C | RNA (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- AL132655.6 | chr20:58840753 G>A | 5'Flank (SNP) | VAF 54/383 reads (14%) | catalogued as rs142690161; called by muse, mutect2, varscan2
- FN1 | c.3797-1305C>A | Intron (SNP) | VAF 106/509 reads (21%) | called by muse, mutect2, varscan2
- LINC02118 | n.192G>T | RNA (SNP) | VAF 60/266 reads (23%) | called by muse, mutect2, varscan2
- NTN1 | c.1411+285G>A | Intron (SNP) | VAF 40/355 reads (11%) | catalogued as rs1469548420; called by muse, mutect2, varscan2
- OR2M1P | n.325G>C | RNA (SNP) | VAF 78/648 reads (12%) | called by muse, mutect2, varscan2
- PACC1 | c.36+746C>A | Intron (SNP) | VAF 26/212 reads (12%) | catalogued as rs939252706; called by muse, mutect2, varscan2
- PDE9A | c.*12G>T | 3'UTR (SNP) | VAF 20/131 reads (15%) | catalogued as rs1386671437; called by muse, mutect2, varscan2
- PLA2G4C | c.568+16G>C | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2
- SPATA31C2 | n.996G>A | RNA (SNP) | VAF 18/469 reads (4%) | called by muse, mutect2
- WFDC10B | c.-190A>T | 5'UTR (SNP) | VAF 19/453 reads (4%) | called by muse, mutect2
- ZNF827 | c.*214G>T | 3'UTR (SNP) | VAF 38/162 reads (23%) | catalogued as COSV101061964; called by muse, mutect2, varscan2
